Surgical pathology report (de-identified scan), TCGA case TCGA-12-1098, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Duke, specimen TCGA-12-1098-01C (Primary Tumor).

[page 1 of 2]
Patient: [REDACTED]

12-1098

AP Surgical Pathology: Additional Info [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:

[REDACTED] is a [REDACTED] with medical hx significant for [REDACTED] and diverticulitis when she started to suffer episodes of confusion and memory loss.

[REDACTED] MRI reveals a left frontal lobe tumor

GROSS EXAMINATION:

A. "Brain tissue (AF1)". Received fresh for frozen section is a 3.5 x 2.9 x 1.2 cm aggregate of soft pink-tan tissue with well demarcated white and gray mater. Portion of tissue was frozen as representative AF1 and the frozen section remnant is submitted in block A1 and additional representative sections are submitted in blocks A2-A4 and the remainder is retained in formalin.

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue": AF1- glioma, high-grade [REDACTED].

MICROSCOPIC EXAMINATION:

The tissue is brain that exhibits a neoplastic proliferation of small and intermediate size astrocytes associated with pseudopalisading necrosis and modest vascular proliferation lacking endothelial proliferation.

DIAGNOSIS:

A. "BRAIN TISSUE" (CRANIOTOMY):

GLIOBLASTOMA (WHO GRADE IV).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

ADDENDUM 1:

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

FISH INTERPRETATION SUMMARY:

CHROMOSOME 7 CENTROMERE - POLYSOMY (72% OF TUMOR CELLS EXHIBIT POLYSOMY)

EGFR - POLYSOMY (78% OF TUMOR CELLS EXHIBIT POLYSOMY)

CHROMOSOME 10 CENTROMERE - INTACT (NO LOSS)

PTEN - INTACT (NO LOSS)

9P21 - INTACT (NO LOSS)

CHROMOSOME 9 CENTROMERE - INTACT (NO LOSS)

2 OF 4 ABNORMAL MARKERS.

COMMENT: A MULTIVARIATE SURVIVAL ANALYSIS OF [REDACTED] PATIENTS WITH GLIOBLASTOMAS REVEALS THAT THE HAZARD OF SHORT SURVIVAL AMONG PATIENTS WITH 0-2 ABNORMAL

[page 2 of 2]
MARKERS (OUT OF 4) WAS SIGNIFICANTLY LOWER THAN THAT FOUND WITH PATIENTS WITH 4 ABNORMAL MARKERS EVEN AFTER ADJUSTMENT FOR AGE EFFECT.

12-1098

PTEN IMMUNOHISTOCHEMISTRY DEMONSTRATES A LOSS WHILE FISH INDICATES BOTH ALLELES TO BE INTACT. EPIGENETIC MECHANISMS SUCH AS METHYLATION CAN EXPLAIN THIS APPARENT DISCREPANCY.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

ADDENDUM 2:

IMMUNOHISTOCHEMICAL LABELING INDEX OF TUMOR CELLS:

TISSUE TYPE: BRAIN TISSUE CONTAINING GLIOBLASTOMA (WHO GRADE IV; [REDACTED], BLOCK A2).

PROLIFERATION INDEX INTERPRETATION: HIGH PROLIFERATION INDEX (20% OF TUMOR CELLS EXHIBIT STAINING).

LEUCOCYTE COMMON ANTIGEN (LCA): 40% OF POSITIVE CELLS.

MGMT - NEGATIVE (10% OF TUMOR CELLS)

EGFR wt - POSITIVE (2-3+ IN 90% OF TUMOR CELLS)

EGFR vIII - NEGATIVE (0% OF TUMOR CELLS)

PTEN - LOSS (2+ IN 60% OF TUMOR CELLS)

S6 - NEGATIVE (2+ IN 20% OF TUMOR CELLS)

AKT - POSITIVE (2+ IN 80% OF TUMOR CELLS)

MAPK - POSITIVE (2+ IN 80% OF TUMOR CELLS)

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

Performed by: [REDACTED]

Source: NCI Genomic Data Commons file 0611a29d-d87d-4672-99b6-8e8b16095031 (TCGA-12-1098.E7904644-81DB-46FF-A120-4A8006AE6B2B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).